Somatic mutation profile of tumor specimen MP2PRT-PAVSPM-TMP1-A (aliquot MP2PRT-PAVSPM-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVSPM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,955 days).
Specimen MP2PRT-PAVSPM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0945bb1-0739-4a17-a8db-6154e31c00e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSPM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSPM-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acfa9a11-3bcd-42fb-a192-b5f4fac78e64

The open-access MAF lists 58 somatic variants for this specimen: 46 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 10, Splice Site 2, Intron 2, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2CL | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 15/529 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV59670994; called by muse, mutect2
- AMER3 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 19/577 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV58466914; called by muse, mutect2
- BPIFC | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as rs897044202, COSV55913203, COSV55916336; called by muse, mutect2
- C6orf120 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 31/767 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV59323091; called by muse, mutect2
- CATSPERB | c.2804C>T p.S935L | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1356348990, COSV56429545; called by muse, mutect2, varscan2
- DDO | c.770G>A p.R257Q (on ENST00000368924 / NM_001368172.1; = p.R198Q on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/507 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs755822127, COSV64470442; called by muse, mutect2
- DIS3L | c.846G>A p.M282I (on ENST00000319212 / NM_001143688.3; = p.M199I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59912357; called by muse, mutect2
- DMRTC1 | c.489C>G p.F163L | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781918204; called by muse, mutect2
- FAM71F1 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 31/455 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs148960534; called by muse, mutect2
- FLG2 | c.4397G>C p.G1466A | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV66166758; called by muse, mutect2
- FMO4 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100882036, COSV63001947; called by muse, mutect2
- GAB1 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs1381835671; called by muse, mutect2
- LRP4 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66136774; called by muse, mutect2
- MYOM3 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs779278585; called by muse, mutect2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by muse, mutect2
- RUNX1T1 | c.1559G>A p.R520H (on ENST00000265814 / NM_001198628.1; = p.R493H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1471788722, COSV56138082, COSV56155262; called by muse, mutect2
- SIM1 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 19/506 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as rs1327417874, COSV53494928; called by muse, mutect2
- SIN3A | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 140/410 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as COSV64583257; called by muse, mutect2, varscan2
- SLC30A8 | c.573-1G>C p.X191_splice | Splice Site (SNP) | VAF 8/256 reads (3%) | catalogued as COSV101438253; called by muse, mutect2
- ANKRD17 | c.3617G>C p.G1206A | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGEF1 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF1 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CETN1 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.49); called by muse, mutect2
- COBLL1 | c.1780G>C p.E594Q (on ENST00000392717; = p.E556Q on NM_014900.5) | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.106); called by muse, mutect2
- CUBN | c.6824G>C p.C2275S | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DACT2 | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 20/672 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2
- DDX60L | c.1165A>T p.I389F | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- EIF2AK3 | c.985C>G p.L329V | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); called by muse, mutect2
- ERFL | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 45/471 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2
- HRG | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- ING1 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 62/719 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- LRP4 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); called by muse, mutect2
- LRSAM1 | c.529-1G>A p.X177_splice | Splice Site (SNP) | VAF 15/391 reads (4%) | called by muse, mutect2
- MAP4K5 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- MBD1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 21/532 reads (4%) | called by muse, mutect2
- MFSD10 | c.624_625insACC p.L208_L209insT | In Frame Ins (INS) | VAF 119/451 reads (26%) | called by mutect2, pindel, varscan2
- MIA3 | c.4981C>G p.L1661V | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- MICAL3 | c.3713C>T p.S1238L | Missense Mutation (SNP) | VAF 26/631 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); called by muse, mutect2
- MMP25 | c.339C>G p.S113R | Missense Mutation (SNP) | VAF 138/448 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- NRK | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- PURG | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- SPOCK3 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ST14 | c.730T>C p.C244R | Missense Mutation (SNP) | VAF 23/703 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2
- TAF1L | c.21G>T p.L7F | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- THAP6 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.283); called by muse, mutect2
- USP42 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM11 | c.1986G>C p.L662= | Silent (SNP) | VAF 207/572 reads (36%) | called by muse, mutect2, varscan2
- ATG16L1 | c.519T>C p.F173= | Silent (SNP) | VAF 19/376 reads (5%) | called by muse, mutect2
- KIF1A | c.2631C>T p.G877= | Silent (SNP) | VAF 167/481 reads (35%) | catalogued as rs751977290, COSV57494486; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYLK | c.2616G>T p.V872= | Silent (SNP) | VAF 239/712 reads (34%) | called by muse, mutect2
- PCDHA1 | c.1446G>A p.A482= | Silent (SNP) | VAF 34/790 reads (4%) | catalogued as rs1428091500; called by muse, mutect2
- RFX6 | c.2475C>T p.I825= | Silent (SNP) | VAF 15/493 reads (3%) | called by muse, mutect2
- TBC1D9B | c.2028C>T p.L676= | Silent (SNP) | VAF 19/578 reads (3%) | called by muse, mutect2
- TTC39B | c.1539G>A p.E513= | Silent (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- WDFY4 | c.1941C>T p.F647= | Silent (SNP) | VAF 19/466 reads (4%) | called by muse, mutect2
- ZAN | c.3211C>A p.R1071= | Silent (SNP) | VAF 38/506 reads (8%) | catalogued as COSV100769663; called by muse, mutect2
- FGFR2 | c.2301+1525G>C | Intron (SNP) | VAF 9/265 reads (3%) | called by muse, mutect2
- VSTM4 | c.457+3740C>T | Intron (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
